Somatic mutation profile of tumor specimen MMRF_1694_4_BM_CD138pos (aliquot MMRF_1694_4_BM_CD138pos_T1_KHS5U_L16541) from MMRF case MMRF_1694, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.9 years (24,422 days).
Specimen MMRF_1694_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e280cff-6977-4f4a-90f7-75f7f21c43bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1694_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1694_1_PB_Whole_C3_KBS5U_L04807; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c73130f8-7800-4985-82da-af7a270109cf

The open-access MAF lists 88 somatic variants for this specimen: 38 protein-altering or splice-affecting, 14 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 15, Silent 14, Intron 10, 5'UTR 7, Nonsense Mutation 3, RNA 2, In Frame Del 2, 3'Flank 1, 5'Flank 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYO15A | c.4198G>A p.V1400M | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749136456, CM105323; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5519G>A p.R1840H | Missense Mutation (SNP) | VAF 119/282 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs563366603, COSV51851942; called by muse, mutect2, varscan2
- ANO5 | c.2613G>A p.M871I | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs372387443; called by muse, mutect2, varscan2
- ATP10D | c.3588C>G p.F1196L | Missense Mutation (SNP) | VAF 122/417 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs367938126, COSV56707511; called by muse, mutect2, varscan2
- CD274 | c.720C>A p.H240Q | Missense Mutation (SNP) | VAF 118/256 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as COSV67501738; called by muse, mutect2, varscan2
- CSMD3 | c.1208A>T p.N403I | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.177); catalogued as COSV52241389; called by muse, mutect2, varscan2
- DMD | c.7576C>T p.Q2526* | Nonsense Mutation (SNP) | VAF 30/192 reads (16%) | catalogued as CM098444; called by muse, mutect2, varscan2
- FRYL | c.206A>T p.H69L | Missense Mutation (SNP) | VAF 102/198 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs1443397225; called by muse, mutect2, varscan2
- FZD10 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 132/136 reads (97%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as rs1185084864, COSV57472150, COSV57472925; called by muse, mutect2, varscan2
- GUCA1A | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV50003456; called by muse, mutect2, varscan2
- IHH | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 83/183 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs749777278; called by muse, mutect2, varscan2
- KRTAP20-2 | c.122G>T p.R41L | Missense Mutation (SNP) | VAF 82/271 reads (30%) | PolyPhen benign (0); catalogued as rs747702388; called by muse, mutect2, varscan2
- MYO1F | c.1976C>T p.A659V | Missense Mutation (SNP) | VAF 112/199 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as rs201138222, COSV57796026; called by muse, mutect2, varscan2
- NOL4 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs774936266, COSV52357422, COSV99307946; called by muse, mutect2, varscan2
- SLC39A12 | c.326_328del p.E109del | In Frame Del (DEL) | VAF 26/48 reads (54%) | catalogued as rs782682656; called by pindel, varscan2
- ATP2B3 | c.2342C>G p.T781S | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- AUTS2 | c.178G>C p.G60R | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CCDC114 | c.1190G>A p.G397E | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC186 | c.2058A>T p.K686N | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- CEP112 | c.2066A>C p.D689A | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- CLCN6 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CYLC2 | c.1031A>G p.K344R | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT tolerated, low confidence (0.63); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- HEPHL1 | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 76/179 reads (42%) | called by muse, mutect2, varscan2
- HID1 | c.2023A>T p.S675C | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- IGHV1-69D | c.275A>G p.D92G | Missense Mutation (SNP) | VAF 146/663 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); called by muse, mutect2
- NONO | c.1204_1208dup p.A404Pfs*18 | Frame Shift Ins (INS) | VAF 30/44 reads (68%) | called by pindel, varscan2
- NPAT | c.1455T>G p.I485M | Missense Mutation (SNP) | VAF 60/115 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- PCDH7 | c.1805C>T p.T602I | Missense Mutation (SNP) | VAF 83/195 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- PLEKHA2 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PSMA1 | c.136T>G p.L46V | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- PTPRJ | c.1378T>G p.F460V | Missense Mutation (SNP) | VAF 73/133 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- QSOX2 | c.1079T>C p.L360S | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RBM42 | c.899T>A p.L300H | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- SAMD9 | c.607A>G p.T203A | Missense Mutation (SNP) | VAF 105/226 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- SMURF1 | c.498_504delinsGATG p.G167_P168delinsM | In Frame Del (DEL) | VAF 25/73 reads (34%) | called by pindel, varscan2*
- TFR2 | c.1046C>A p.S349* | Nonsense Mutation (SNP) | VAF 7/134 reads (5%) | called by muse, mutect2
- TMEM266 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- UCKL1 | c.924G>A p.R308= | Splice Region (SNP) | VAF 36/71 reads (51%) | called by muse, mutect2, varscan2
- ACTA2 | c.660T>C p.Y220= | Silent (SNP) | VAF 27/94 reads (29%) | called by muse, mutect2, varscan2
- DDX4 | c.1110T>C p.I370= | Silent (SNP) | VAF 6/147 reads (4%) | called by muse, mutect2
- DST | c.16218C>T p.S5406= (on ENST00000361203 / NM_001374722.1; = p.S2994= on NM_015548.5) | Silent (SNP) | VAF 116/226 reads (51%) | called by muse, mutect2, varscan2
- HDGFL1 | c.219C>T p.R73= | Silent (SNP) | VAF 139/271 reads (51%) | called by muse, mutect2, varscan2
- HYOU1 | c.816C>T p.G272= | Silent (SNP) | VAF 64/153 reads (42%) | called by muse, mutect2, varscan2
- IGKV3-20 | c.327T>C p.C109= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs1204306661; called by muse, mutect2, varscan2
- IGKV3-20 | c.36A>G p.L12= | Silent (SNP) | VAF 24/27 reads (89%) | catalogued as rs762981285; called by muse, mutect2, varscan2
- IGLV4-60 | c.231C>T p.Y77= | Silent (SNP) | VAF 125/130 reads (96%) | catalogued as rs567096325, COSV66503515; called by muse, mutect2, varscan2
- IQGAP2 | c.1278A>G p.Q426= | Silent (SNP) | VAF 44/83 reads (53%) | called by muse, mutect2, varscan2
- KCNT2 | c.1467C>T p.V489= | Silent (SNP) | VAF 61/200 reads (31%) | catalogued as rs747959439, COSV54106028; called by muse, mutect2, varscan2
- NEB | c.1347C>T p.V449= | Silent (SNP) | VAF 64/124 reads (52%) | called by muse, mutect2, varscan2
- NFKBIB | c.834C>T p.L278= | Silent (SNP) | VAF 54/120 reads (45%) | catalogued as rs750595727; called by muse, mutect2, varscan2
- STYK1 | c.81T>A p.I27= | Silent (SNP) | VAF 74/76 reads (97%) | called by muse, mutect2, varscan2
- TCF25 | c.1866C>A p.T622= | Silent (SNP) | VAF 96/103 reads (93%) | called by muse, mutect2, varscan2
- ACTB | c.-27-121G>A | Intron (SNP) | VAF 110/239 reads (46%) | catalogued as rs533676634, COSV59317189; called by muse, mutect2, varscan2
- ALG3 | c.605+50T>A | Intron (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- ANKRD31 | c.-124C>T | 5'UTR (SNP) | VAF 16/131 reads (12%) | catalogued as rs973448121; called by muse, mutect2, varscan2
- ARL5C | c.107+87T>C | Intron (SNP) | VAF 52/86 reads (60%) | called by muse, mutect2, varscan2
- C9orf62 | n.58T>C | RNA (SNP) | VAF 44/96 reads (46%) | called by muse, mutect2, varscan2
- CAPN8 | c.1136-999G>A | Intron (SNP) | VAF 35/82 reads (43%) | called by muse, mutect2, varscan2
- CCDC69 | c.-117C>T | 5'UTR (SNP) | VAF 102/210 reads (49%) | called by muse, mutect2
- CNNM4 | c.*744G>A | 3'UTR (SNP) | VAF 82/150 reads (55%) | called by muse, mutect2, varscan2
- ESPNP | n.1458G>A | RNA (SNP) | VAF 34/133 reads (26%) | catalogued as rs1226900715; called by muse, mutect2, varscan2
- F2R | c.*494A>G | 3'UTR (SNP) | VAF 55/115 reads (48%) | called by muse, mutect2, varscan2
- H2BC8 | c.*68T>G | 3'UTR (SNP) | VAF 96/210 reads (46%) | called by muse, mutect2, varscan2
- HERPUD2 | c.*933G>C | 3'UTR (SNP) | VAF 17/67 reads (25%) | called by muse, mutect2, varscan2
- HMGB4 | c.-1194C>T | 5'UTR (SNP) | VAF 58/108 reads (54%) | called by muse, mutect2, varscan2
- IGHV3-7 | c.-63C>T | 5'UTR (SNP) | VAF 66/129 reads (51%) | called by muse, mutect2, varscan2
- IL36RN | c.*1149C>T | 3'UTR (SNP) | VAF 36/69 reads (52%) | called by muse, mutect2, varscan2
- LARP4B | c.*402G>A | 3'UTR (SNP) | VAF 53/128 reads (41%) | catalogued as rs78608705; called by muse, mutect2, varscan2
- LOXHD1 | c.-6G>C | 5'UTR (SNP) | VAF 63/124 reads (51%) | called by muse, mutect2, varscan2
- NPY2R | c.*29G>A | 3'UTR (SNP) | VAF 136/272 reads (50%) | called by muse, mutect2, varscan2
- NREP | c.*431A>G | 3'UTR (SNP) | VAF 82/166 reads (49%) | catalogued as rs759845984; called by muse, mutect2, varscan2
- NSD2 | c.1881+2951T>G | Intron (SNP) | VAF 21/98 reads (21%) | called by muse, mutect2, varscan2
- PEG10 | c.*797A>T | 3'UTR (SNP) | VAF 235/504 reads (47%) | called by muse, mutect2, varscan2
- PRDM13 | c.*588A>C | 3'UTR (SNP) | VAF 35/72 reads (49%) | called by muse, mutect2, varscan2
- PUS7L | c.*1056A>C | 3'UTR (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- PYGO1 | c.49+895G>C | Intron (SNP) | VAF 147/340 reads (43%) | catalogued as rs202218683; called by muse, mutect2, varscan2
- RANBP1 | c.505+248C>T | Intron (SNP) | VAF 66/67 reads (99%) | called by muse, mutect2, varscan2
- RPS6KB1 | c.-29G>C | 5'UTR (SNP) | VAF 33/57 reads (58%) | called by muse, mutect2, varscan2
- SHMT1 | c.1055-47C>T | Intron (SNP) | VAF 30/58 reads (52%) | catalogued as rs373836244; called by muse, mutect2, varscan2
- SLC5A12 | c.*583_*586delinsAC | 3'UTR (DEL) | VAF 9/58 reads (16%) | called by mutect2*, pindel, varscan2*
- SYNPO2L | c.257+13C>G | Intron (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- TMEM132E | chr17:34578956 C>G | 5'Flank (SNP) | VAF 172/376 reads (46%) | called by muse, mutect2, varscan2
- TWIST2 | c.-7G>A | 5'UTR (SNP) | VAF 37/58 reads (64%) | called by muse, mutect2, varscan2
- UBE2I | c.*1534C>T | 3'UTR (SNP) | VAF 91/161 reads (57%) | catalogued as rs1322446131; called by muse, mutect2, varscan2
- UNC5D | c.*5471C>T | 3'UTR (SNP) | VAF 8/58 reads (14%) | catalogued as rs1173686079; called by muse, mutect2, varscan2
- USP17L30 | chr4:9369029 T>C | 3'Flank (SNP) | VAF 42/114 reads (37%) | catalogued as rs1200951437; called by muse, mutect2, varscan2
- ZFHX2 | c.*568C>T | 3'UTR (SNP) | VAF 65/68 reads (96%) | called by muse, mutect2, varscan2
- ZNF711 | c.-26-116T>G | Intron (SNP) | VAF 49/50 reads (98%) | called by muse, mutect2, varscan2
